Surgical pathology report (de-identified scan), TCGA case TCGA-DJ-A3UO, project TCGA-THCA (Thyroid Carcinoma), tissue source site Memorial Sloan Kettering, specimen TCGA-DJ-A3UO-01A (Primary Tumor).

[page 1 of 3]
	bw 1/30/12	

ck
neck

Date of Procedure:
Date of Receipt:
Date of Report:
Account #:
Billing Type:
Additional Copy to:

Clinical Diagnosis & History:

year old with left papillary thyroid carcinoma and right thyroid nodule showing atypical cells.

Specimens Submitted:

- 1: Right paratracheal tissue, excision (fs)
- 2: Right level three and four lymph nodes, excision
- 3: Left neck level three and four lymph nodes, excision (fs)
- 4: Thyroid, total thyroidectomy
- 5: Left paratracheal tissue, excision

DIAGNOSIS:

1. Right paratracheal tissue, excision (fs):

Lymph Node Dissection:

Metastatic papillary thyroid carcinoma
Number of lymph nodes examined: 1
Number of lymph nodes with metastatic disease: 1
Size of the largest lymph node involved by tumor: 0.5cm.
Size of the largest metastatic focus : 0.5 cm.
Extranodal extension is identified

ICD-O3

carcinoma, papillary, thyroid

8260/3

Site: thyroid, nos

C73.9

S212
RP

2. Right level three and four lymph nodes, excision:

Lymph Node Dissection:

Metastatic papillary thyroid carcinoma
Number of lymph nodes examined: 10
Number of lymph nodes with metastatic disease: 2
Size of the largest lymph node involved by tumor: 0.9cm.
Size of the largest metastatic focus : 0.3 cm.
Extranodal extension is identified

3. Left neck level three and four lymph nodes, excision (fs):

Lymph Node Dissection:

Benign lymph nodes
Number of lymph nodes examined: 11

4. Thyroid, total thyroidectomy:

Tumor Type:

Papillary carcinoma, classical type
Two foci

Histologic Grade:

Well differentiated

[page 2 of 3]
Mitotic Activity:

Not identified

Tumor Necrosis:

Not identified

Tumor Location:

Left lobe

Right lobe

Tumor Size:

The tumor foci measure 2.8 cm (right lobe) and 1.5 cm (left lobe) in greatest dimension

Tumor Encapsulation:

None identified

Blood Vessel Invasion:

Identified, at 3 foci of vascular invasion including a focus in the extrathyroidal tissue

Extrathyroid Extension:

Invades: perithyroid fibroadipose tissue

Surgical Margins:

Free of tumor

Tumor Multicentricity:

Gross foci present

Non-Neoplastic Thyroid:

No abnormalities identified

Parathyroid Glands:

Identified

One unremarkable parathyroid gland in the left lobe

Lymph Nodes:

Metastatic papillary carcinoma involving one lymph node (1/1). the lymph node measures 0.7 cm and is almost totally replaced by tumor

5. Left paratracheal tissue, excision:

Lymph Node Dissection:

Metastatic papillary thyroid carcinoma

Number of lymph nodes examined: 2

Number of lymph nodes with metastatic disease: 2

Size of the largest lymph node involved by tumor: 0.4cm.

Size of the largest metastatic focus: 0.4 cm.

Extranodal extension is not identified

Benign parathyroid gland is identified.

I ATTEST THAT THE ABOVE DIAGNOSIS IS BASED UPON MY PERSONAL EXAMINATION OF THE SLIDES (AND/OR OTHER MATERIAL), AND THAT I HAVE REVIEWED AND APPROVED THIS REPORT.

*** Report Electronically Signed Out ***

Gross Description:

[page 3 of 3]
1. The specimen is received fresh, labeled "Right paratracheal tissue". It consists of fat and a lymph node measuring 1.8 x 0.6 x 0.3 cm. The lymph node measures 0.6 x 0.5 x 0.3 cm. The lymph node is submitted entirely for frozen section.

Summary of Sections:

FSC- frozen section control

2. The specimen is received fresh, labeled "right level three and four lymph nodes" and consists of multiple possible lymph nodes measuring from 0.2 cm up to 1.0 cm in greatest dimensions. All possible lymph nodes are entirely submitted.

Summary of sections:

LN - lymph nodes

3. The specimen is received fresh, labeled "Left neck level III and IV lymph nodes". It consists of fat and lymph nodes. The lymph nodes range in size from 0.1 to 1.1 cm in greatest dimension. The lymph nodes are submitted entirely for frozen section. The remaining fat is entirely submitted.

Summary of Sections:

FSCA - frozen section control, approximately 5 lymph nodes

FSCB - frozen section control, two lymph nodes

RS - remaining fat with possible lymph nodes

4. The specimen is received fresh, labeled "total thyroidectomy, stitch marks left lobe of thyroid" and consists of a thyroid weighing 30.5 g. The right lobe measures 3.0 x 2.0 x 2.0 cm, the left lobe measures 2.5 x 2.0 x 1.5 cm and the isthmus measures 1.0 x 0.5 x 0.5 cm. The external surface is covered by a thin fibrous capsule. The posterior surface of the specimen is inked black, and the anterior is inked blue. Sectioning reveals one large previously open nodule in the right lobe measuring 2.8 x 1.8 x 1.0 cm. Sections through the remaining tissue reveal a nodule in the left lobe measuring 1.5 x 1.5 x 1.2 cm. The left lobe also contains another second smaller nodule measuring 0.7 x 0.3 x 0.2 cm. The remaining thyroid parenchyma is red tan and beefy. Representative sections of the specimen are submitted for . The remaining tissue is serially sectioned and representatively submitted.

Summary of sections:

RN - right nodule

LN (1)- Left nodule

LN (2)- left lobe

RL - right lobe

LL - left lobe

IS - isthmus

5. The specimen is received fresh, labeled "left paratracheal tissue" and consists of an irregular piece of adipose tissue measuring 3.0 x 2.0 x 0.4 cm. It is dissected to reveal a lymph node measuring 0.3 x 0.3 x 0.3 cm. All identified lymph nodes are submitted.

Summary of sections:

LN - lymph nodes

AD- rest of adipose tissue

Summary of Sections:

Part 1: Right paratracheal tissue, excision (fs)

Block	Sect. Site	PCs
1	FSC	1

Part 2: Right level three and four lymph nodes, excision

Block	Sect. Site	PCs
4	LN	4

Part 3: Left neck level three and four lymph nodes, excision (fs)

Source: NCI Genomic Data Commons file 82d934be-28f1-4153-8cc3-dc9868be0ee4 (TCGA-DJ-A3UO.53819A9B-A594-445D-BD36-BB29B7FC0607.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).